CCDI case PBBVNH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/17073a64-f8b0-4c1f-9bb8-613bf637a001

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.6 years (1,317 days).

Biospecimens (4 samples)
- Sample 0DIMVQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIMWL: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DIMWZ: Tissue type: Tumor; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DITT3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
